Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A73B, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A73B-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular NOS
Site Liver C22.0 8770/3
JW

Female

DIAGNOSIS:

A. Liver, left, partial hepatectomy: Hepatocellular carcinoma, moderately differentiated (grade 2 of 4), forming a single mass, 4.3 x 4.1 x 4.0 cm. The tumor is confined to the liver. The liver parenchyma resection margin is negative for tumor (tumor free margin, 1.4 cm). Macroscopic large vessel invasion is absent. Microscopic invasion is absent. No regional lymph nodes identified.

B. Gallbladder, cholecystectomy: Chronic cholecystitis and cholelithiasis with two benign lymph nodes.

With available surgical material, [AJCC pT1] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

Interpreted by:
Report electronically signed by
Transcribed by:

ADDENDUM:

The non-neoplastic liver shows established cirrhosis (stage 4 of 4), morphologically cryptogenic. The iron stain shows minimal hemosiderosis.

Source: NCI Genomic Data Commons file 4520e174-ccf1-458a-a2d8-54d2191e40db (TCGA-DD-A73B.B1C57A75-7C86-49D9-B143-09E60824F508.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).